Somatic mutation profile of tumor specimen C3N-00242-01 (aliquot CPT0014450007) from CPTAC case C3N-00242, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 69.4 years (25,345 days).
Specimen C3N-00242-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 232adc1a-e78a-4783-811b-201a0766f321.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00242-31 (Blood Derived Normal), aliquot CPT0015070002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89bb6c84-0b8d-473c-99cf-a6155be18a06

The open-access MAF lists 97 somatic variants for this specimen: 74 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 14, Nonsense Mutation 8, Frame Shift Del 7, Intron 3, 3'UTR 3, Splice Site 2, In Frame Ins 2, 5'UTR 2, Splice Region 2, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP9B | c.1718C>G p.A573G | Missense Mutation (SNP) | VAF 156/392 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.353); catalogued as rs894107927; called by muse, varscan2
- BCLAF1 | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100787149; called by muse, mutect2, varscan2
- BUB1 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100241149; called by muse, mutect2, varscan2
- CCR3 | c.383C>A p.T128K | Missense Mutation (SNP) | VAF 101/136 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776923069; called by muse, mutect2, varscan2
- COL5A1 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 126/168 reads (75%) | SIFT tolerated (0.23); PolyPhen benign (0.232); catalogued as rs148548209, COSV65669151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSMD1 | c.4892C>G p.T1631R (on ENST00000520002; = p.T1630R on NM_033225.6) | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV59283469; called by muse, mutect2, varscan2
- DXO | c.1090T>A p.S364T | Missense Mutation (SNP) | VAF 108/140 reads (77%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1211730106; called by muse, mutect2, varscan2
- FGD5 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 132/170 reads (78%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs370762215; called by muse, mutect2, varscan2
- FMO5 | c.377G>A p.W126* | Nonsense Mutation (SNP) | VAF 42/71 reads (59%) | catalogued as COSV54210758; called by muse, mutect2, varscan2
- HNRNPCL1 | c.187del p.A63Pfs*5 | Frame Shift Del (DEL) | VAF 50/82 reads (61%) | catalogued as COSV100509112; called by mutect2, varscan2
- ITPKC | c.251G>T p.S84I | Missense Mutation (SNP) | VAF 121/263 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs772973828; called by muse, mutect2, varscan2
- KEL | c.1095G>T p.M365I | Missense Mutation (SNP) | VAF 145/530 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1417250801, COSV62334398; called by muse, mutect2, varscan2
- MAST3 | c.3694C>T p.R1232W | Missense Mutation (SNP) | VAF 68/149 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.657); catalogued as rs757453640; called by muse, mutect2, varscan2
- PBRM1 | c.3358C>T p.R1120* (on ENST00000296302 / NM_001366071.2; = p.R1095* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 66/85 reads (78%) | catalogued as COSV56273906; called by mutect2, varscan2
- SERINC5 | c.419G>T p.G140V | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.749); catalogued as COSV101549146, COSV101549148; called by muse, varscan2
- TM4SF1 | c.317A>G p.Y106C | Missense Mutation (SNP) | VAF 76/105 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560003388, COSV59524672; called by muse, mutect2, varscan2
- TYK2 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 79/179 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs373929549; called by muse, mutect2, varscan2
- ALMS1 | c.9737C>A p.S3246* | Nonsense Mutation (SNP) | VAF 134/257 reads (52%) | called by muse, mutect2, varscan2
- AP5B1 | c.689A>G p.E230G | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ARHGEF12 | c.2587C>A p.Q863K | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.115); called by mutect2, varscan2
- ARHGEF12 | c.2636A>C p.K879T | Missense Mutation (SNP) | VAF 107/202 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASH1L | c.7159A>T p.N2387Y (on ENST00000368346 / NM_001366177.2; = p.N2382Y on NM_018489.3) | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- B3GNT9 | c.244T>C p.F82L | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- BCCIP | c.547A>T p.R183* | Nonsense Mutation (SNP) | VAF 59/91 reads (65%) | called by muse, mutect2, varscan2
- BCO2 | c.1474del p.D492Ifs*3 | Frame Shift Del (DEL) | VAF 142/311 reads (46%) | called by mutect2, pindel, varscan2
- BIRC6 | c.8588T>A p.V2863D | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- BRAT1 | c.2444G>C p.G815A | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2
- C12orf56 | c.214C>G p.R72G | Missense Mutation (SNP) | VAF 98/209 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C4orf17 | c.185T>C p.L62S | Missense Mutation (SNP) | VAF 84/112 reads (75%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- C4orf54 | c.4252G>A p.G1418R | Missense Mutation (SNP) | VAF 93/123 reads (76%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCDC87 | c.1926A>C p.E642D | Missense Mutation (SNP) | VAF 101/180 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- CEACAM16 | c.38-1del p.X13_splice | Splice Site (DEL) | VAF 26/60 reads (43%) | called by mutect2, pindel*, varscan2
- CHST3 | c.97A>G p.I33V | Missense Mutation (SNP) | VAF 89/347 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CIR1 | c.793T>A p.S265T | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- CLEC4E | c.264A>T p.Q88H | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- COL27A1 | c.3121C>A p.P1041T | Missense Mutation (SNP) | VAF 49/71 reads (69%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- DSG1 | c.2777_2778insGACAGAAAGAGA p.V926_I927insTERE | In Frame Ins (INS) | VAF 114/431 reads (26%) | called by mutect2, pindel, varscan2
- FAM8A1 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 73/88 reads (83%) | SIFT tolerated (0.07); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FAT3 | c.9803A>G p.N3268S | Missense Mutation (SNP) | VAF 81/122 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- FNIP2 | c.312C>A p.S104R | Missense Mutation (SNP) | VAF 63/81 reads (78%) | SIFT tolerated (0.36); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- HADHA | c.1690-3_1696del p.X564_splice | Splice Site (DEL) | VAF 22/127 reads (17%) | called by mutect2, pindel, varscan2
- HECW1 | c.2875A>G p.T959A | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- HNRNPCL1 | c.186T>A p.N62K | Missense Mutation (SNP) | VAF 51/79 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by mutect2, varscan2
- HOXB4 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ITPRIPL2 | c.293G>A p.S98N | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KDM5C | c.4288_4306del p.D1430Hfs*42 | Frame Shift Del (DEL) | VAF 132/174 reads (76%) | called by mutect2, pindel, varscan2
- KMT2C | c.14690T>G p.I4897S | Missense Mutation (SNP) | VAF 76/361 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MLYCD | c.1013T>A p.L338H | Missense Mutation (SNP) | VAF 161/405 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MNX1 | c.934A>G p.K312E | Missense Mutation (SNP) | VAF 252/952 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- MPP4 | c.1426T>A p.Y476N | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTG1 | c.977del p.G326Afs*31 | Frame Shift Del (DEL) | VAF 30/70 reads (43%) | called by mutect2, pindel, varscan2
- NHLRC1 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 11/324 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.015); called by muse, mutect2
- P4HTM | c.745T>G p.F249V | Missense Mutation (SNP) | VAF 81/100 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PFKFB1 | c.1288T>A p.Y430N | Missense Mutation (SNP) | VAF 81/92 reads (88%) | PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PNLDC1 | c.1523G>A p.W508* | Nonsense Mutation (SNP) | VAF 80/119 reads (67%) | called by muse, mutect2, varscan2
- PRR19 | c.603G>A p.G201= | Splice Region (SNP) | VAF 81/168 reads (48%) | called by muse, mutect2, varscan2
- PRR30 | c.994G>T p.G332W | Missense Mutation (SNP) | VAF 76/309 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PWP1 | c.627_629del p.V210del | In Frame Del (DEL) | VAF 38/86 reads (44%) | called by mutect2, pindel, varscan2
- RASIP1 | c.1717del p.L573Sfs*62 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- RILPL1 | c.997C>T p.R333* | Nonsense Mutation (SNP) | VAF 103/250 reads (41%) | called by muse, mutect2, varscan2
- RUSC1 | c.620T>C p.L207P | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SDS | c.98_123del p.S33Nfs*56 | Frame Shift Del (DEL) | VAF 41/146 reads (28%) | called by mutect2, pindel, varscan2
- SGK1 | c.789T>C p.Y263= | Splice Region (SNP) | VAF 63/75 reads (84%) | called by muse, mutect2, varscan2
- SLC16A9 | c.263T>C p.M88T | Missense Mutation (SNP) | VAF 73/139 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- SLC9A1 | c.2059C>A p.P687T | Missense Mutation (SNP) | VAF 90/153 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- TAOK3 | c.1921C>T p.Q641* | Nonsense Mutation (SNP) | VAF 70/195 reads (36%) | called by muse, mutect2
- TENM4 | c.5829T>A p.Y1943* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | called by muse, varscan2
- TOE1 | c.1175T>G p.L392R | Missense Mutation (SNP) | VAF 61/259 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTC26 | c.1317del p.M440* | Frame Shift Del (DEL) | VAF 56/216 reads (26%) | called by mutect2, pindel, varscan2
- UGT3A2 | c.933A>T p.E311D | Missense Mutation (SNP) | VAF 188/295 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- UPF1 | c.2764A>C p.M922L (on ENST00000599848 / NM_001297549.2; = p.M911L on NM_002911.4) | Missense Mutation (SNP) | VAF 64/151 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- VHL | c.329_337dup p.H110_Y112dup | In Frame Ins (INS) | VAF 96/161 reads (60%) | called by mutect2, varscan2
- VSTM2A | c.581C>G p.S194C | Missense Mutation (SNP) | VAF 70/284 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- ZCCHC14 | c.1715T>C p.V572A (on ENST00000268616; = p.V709A on NM_015144.3) | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ADAMTS8 | c.228G>C p.A76= | Silent (SNP) | VAF 40/195 reads (21%) | called by muse, mutect2
- ATP9B | c.1719T>A p.A573= | Silent (SNP) | VAF 154/384 reads (40%) | called by muse, varscan2
- C9orf50 | c.36C>T p.D12= | Silent (SNP) | VAF 19/27 reads (70%) | called by muse, mutect2, varscan2
- CEP295 | c.7530T>C p.N2510= | Silent (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- IL17RA | c.1812G>A p.E604= | Silent (SNP) | VAF 142/332 reads (43%) | called by muse, mutect2, varscan2
- KATNAL1 | c.624T>C p.D208= | Silent (SNP) | VAF 44/111 reads (40%) | catalogued as rs1053156285; called by muse, mutect2, varscan2
- MIA3 | c.3240A>G p.E1080= | Silent (SNP) | VAF 69/134 reads (51%) | called by muse, mutect2, varscan2
- PCDHAC1 | c.2250T>C p.L750= | Silent (SNP) | VAF 99/167 reads (59%) | called by muse, mutect2, varscan2
- RNF111 | c.1488A>G p.A496= | Silent (SNP) | VAF 139/370 reads (38%) | called by muse, mutect2, varscan2
- SEL1L3 | c.2343C>G p.A781= | Silent (SNP) | VAF 40/64 reads (63%) | called by muse, mutect2, varscan2
- SSUH2 | c.816C>T p.P272= | Silent (SNP) | VAF 30/40 reads (75%) | catalogued as rs374272577; called by muse, mutect2
- TAB2 | c.1003A>C p.R335= | Silent (SNP) | VAF 185/244 reads (76%) | called by muse, mutect2, varscan2
- TRAIP | c.1353G>A p.R451= | Silent (SNP) | VAF 75/115 reads (65%) | catalogued as rs761901770; called by muse, mutect2, varscan2
- UGGT1 | c.1047T>G p.L349= | Silent (SNP) | VAF 47/74 reads (64%) | called by muse, mutect2, varscan2
- ADAMTS8 | chr11:130401815 C>T | 3'Flank (SNP) | VAF 40/129 reads (31%) | called by muse, mutect2, varscan2
- CEACAM3 | c.*16G>T | 3'UTR (SNP) | VAF 51/107 reads (48%) | catalogued as rs782079072; called by muse, mutect2, varscan2
- FBXO22 | c.*621A>T | 3'UTR (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- G6PC3 | c.-173C>T | 5'UTR (SNP) | VAF 33/53 reads (62%) | called by muse, mutect2, varscan2
- GRM8 | c.1357+68053T>G | Intron (SNP) | VAF 122/198 reads (62%) | called by muse, mutect2, varscan2
- IRF7 | c.222+23G>A | Intron (SNP) | VAF 50/86 reads (58%) | catalogued as rs1487450438; called by muse, varscan2
- KPNA3 | c.*288C>G | 3'UTR (SNP) | VAF 53/153 reads (35%) | called by muse, mutect2, varscan2
- RPP21 | c.-1G>A | 5'UTR (SNP) | VAF 24/43 reads (56%) | catalogued as rs533505422; called by mutect2, varscan2
- TMEM87A | c.144+294T>C | Intron (SNP) | VAF 34/95 reads (36%) | called by muse, mutect2, varscan2
